Somatic mutation profile of tumor specimen TCGA-FG-5963-02A (aliquot TCGA-FG-5963-02A-12D-A29Q-08) from TCGA case TCGA-FG-5963, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 23.5 years (8,571 days).
Specimen TCGA-FG-5963-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9008fd55-bfa0-4e40-b1d0-35f0f1715246.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5963-10A (Blood Derived Normal), aliquot TCGA-FG-5963-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02dd1a9e-452a-489e-8b90-6d8ec74214a1

The open-access MAF lists 31 somatic variants for this specimen: 29 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 24, Splice Site 2, Silent 2, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7745dup p.R2583Efs*13 (on ENST00000358273 / NM_001042492.3; = p.R2562Efs*13 on NM_000267.3) | Frame Shift Ins (INS) | VAF 78/242 reads (32%) | catalogued as rs1555536683; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 87/106 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- ATRX | c.6506G>A p.G2169E | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64873861; called by muse, mutect2, varscan2
- B4GALNT2 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV55925088; called by muse, mutect2
- CAPN3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58820758; called by muse, mutect2, varscan2
- CCDC88B | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57265462; called by muse, mutect2, varscan2
- COL22A1 | c.3745G>A p.G1249R | Missense Mutation (SNP) | VAF 120/166 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57330238; called by muse, mutect2, varscan2
- DYM | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs781028696, COSV53981145; called by muse, mutect2, varscan2
- FLG | c.7649G>A p.G2550D | Missense Mutation (SNP) | VAF 217/509 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs144484740, COSV100911393, COSV100912465; called by muse, mutect2, varscan2
- GSPT2 | c.1533T>A p.D511E | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs782490092, COSV61213944; called by muse, mutect2, varscan2
- GUCY2C | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148314105; called by muse, mutect2, varscan2
- IGF1R | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51275210; called by muse, mutect2, varscan2
- ITGA2B | c.1982T>G p.V661G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.91); catalogued as COSV52231927; called by muse, mutect2, varscan2
- KDM4D | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100624205; called by muse, mutect2, varscan2
- KHDRBS2 | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.367); catalogued as COSV99832638; called by muse, mutect2, varscan2
- LILRA1 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV52179475; called by muse, mutect2, varscan2
- LMF2 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53316758; called by muse, mutect2, varscan2
- MAP4K4 | c.3263A>G p.Y1088C (on ENST00000347699 / NM_001242559.2; = p.Y1006C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs778889965, COSV56328420; called by muse, mutect2, varscan2
- MAPRE2 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV55818273; called by muse, mutect2, varscan2
- MYH2 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 112/137 reads (82%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.701); catalogued as rs527337606, COSV55431984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PM20D1 | c.489+1G>C p.X163_splice | Splice Site (SNP) | VAF 50/132 reads (38%) | catalogued as COSV65648682; called by muse, mutect2, varscan2
- TXNDC16 | c.1842+1G>A p.X614_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as COSV55983870; called by muse, mutect2, varscan2
- UMPS | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1017481804, COSV51736654, COSV51739139; called by muse, mutect2, varscan2
- USP37 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51442318; called by muse, mutect2, varscan2
- ZNF630 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as COSV52095623; called by muse, mutect2, varscan2
- ACACA | c.3553G>A p.A1185T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PRRT3 | c.499_506del p.T167Sfs*6 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.138C>T p.A46= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs377042462; called by muse, mutect2, varscan2
- UGT2A3 | c.1041C>T p.A347= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99279734; called by muse, mutect2, varscan2
